Somatic mutation profile of tumor specimen ALCH-B1TG-TTP1-A (aliquot ALCH-B1TG-TTP1-A-3-0-D-A770-36) from ALCHEMIST case ALCH-B1TG, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Spindle cell carcinoma, NOS; Age at diagnosis: 71.9 years (26,276 days).
Specimen ALCH-B1TG-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dddfa9b4-592c-4a3d-8970-616a280c81ea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1TG-NB1-A (Blood Derived Normal), aliquot ALCH-B1TG-NB1-A-1-0-D-A770-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0c236cdf-00c1-406b-8bcb-b947713e1e5a

The open-access MAF lists 580 somatic variants for this specimen: 378 protein-altering or splice-affecting, 113 silent, 89 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 320, Silent 113, Intron 39, Nonsense Mutation 33, RNA 17, 3'UTR 11, 5'Flank 11, Frame Shift Del 8, 5'UTR 8, Splice Site 6, Splice Region 6, Frame Shift Ins 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 17/53 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs11552822, CM085316, CM990358, COSV58683210, COSV58683289, COSV58686242, COSV58694349; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 23/54 reads (43%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- SF3B1 | c.1998G>C p.K666N | Missense Mutation (SNP) | VAF 11/75 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs377023736, COSV59205777, COSV59205799; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.731G>T p.G244V | Missense Mutation (SNP) | VAF 31/113 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs985033810, CM056069, CM070298, COSV52661058, COSV52724858, COSV52839584; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS19 | c.3605G>T p.R1202M | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50741501; called by muse, mutect2, varscan2
- ADCY8 | c.527G>A p.G176D | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0.145); catalogued as rs1176410001; called by muse, varscan2
- ADGRF2 | c.314C>T p.P105L (on ENST00000296862 / NM_001368115.2; = p.P37L on NM_153839.7) | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.214); catalogued as rs772766494; called by muse, mutect2, varscan2
- AGPAT4 | c.1057C>T p.R353* | Nonsense Mutation (SNP) | VAF 17/73 reads (23%) | catalogued as COSV100211718; called by muse, mutect2, varscan2
- ALX4 | c.74C>T p.S25L | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.097); catalogued as rs1252436146; called by muse, mutect2, varscan2
- ANO1 | c.853G>A p.D285N | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs765971585, COSV60282295; called by muse, mutect2, varscan2
- AOX1 | c.503C>T p.S168L | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.07); catalogued as rs368656069; called by mutect2, varscan2
- AP3B1 | c.989C>G p.S330C | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV54891375; called by muse, mutect2, varscan2
- ARHGAP17 | c.303G>C p.E101D | Missense Mutation (SNP) | VAF 7/140 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as COSV51506284, COSV99253764; called by muse, mutect2
- C1orf141 | c.19G>C p.E7Q | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.014); catalogued as COSV63992172; called by muse, mutect2, varscan2
- CAPRIN1 | c.62C>T p.S21L | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV100404187; called by muse, mutect2, varscan2
- CCDC18 | c.131C>G p.S44C | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as COSV100159280; called by muse, mutect2, varscan2
- CCL21 | c.342G>C p.K114N | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.521); catalogued as COSV104389000; called by muse, mutect2, varscan2
- CDH26 | c.2375G>T p.G792V (on ENST00000348616 / NM_177980.4; = p.G125V on NM_021810.6) | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.025); catalogued as rs762888225; called by muse, mutect2, varscan2
- CDH6 | c.1807G>A p.E603K | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.589); catalogued as COSV54064950; called by muse, mutect2, varscan2
- CDKN2C | c.214G>T p.A72S | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as rs771853517, COSV52954362, COSV52954434; called by mutect2, varscan2
- CDT1 | c.374C>T p.S125L | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.019); catalogued as rs764961494, COSV99967075; called by muse, mutect2, varscan2
- CENPF | c.5861C>T p.S1954L | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.6); PolyPhen benign (0.03); catalogued as rs1257572014, COSV65276163; called by muse, mutect2
- CGNL1 | c.3517C>T p.Q1173* | Nonsense Mutation (SNP) | VAF 16/62 reads (26%) | catalogued as rs1461703741; called by muse, mutect2, varscan2
- CHL1 | c.2269C>A p.P757T (on ENST00000397491 / NM_001253387.1; = p.P773T on NM_006614.4) | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.219); catalogued as COSV99851349; called by muse, mutect2, varscan2
- CIBAR2 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1157135147; called by muse, mutect2, varscan2
- CNTNAP2 | c.2287G>C p.D763H | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV62245844; called by muse, mutect2
- COL15A1 | c.1219C>G p.R407G | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV66647461; called by muse, mutect2, varscan2
- COPS7A | c.-41C>G | Splice Region (SNP) | VAF 5/22 reads (23%) | catalogued as rs894494744; called by muse, mutect2, varscan2
- CPXM2 | c.1399G>A p.E467K | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV99581475; called by mutect2, varscan2
- CSHL1 | c.410C>T p.S137L (on ENST00000309894 / NM_022581.3; = p.S43L on NM_001318.4) | Missense Mutation (SNP) | VAF 14/167 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.179); catalogued as COSV51987646; called by muse, mutect2
- CTBP2 | c.1315C>T p.R439* | Nonsense Mutation (SNP) | VAF 12/101 reads (12%) | catalogued as rs1388220046, COSV100456171; called by muse, mutect2, varscan2
- DAXX | c.638C>G p.S213* | Nonsense Mutation (SNP) | VAF 8/73 reads (11%) | catalogued as COSV56469996; called by muse, mutect2, varscan2
- DEAF1 | c.69_98del p.A24_A33del | In Frame Del (DEL) | VAF 7/47 reads (15%) | catalogued as rs754135731; called by mutect2, varscan2*
- DIDO1 | c.2437-1G>T p.X813_splice | Splice Site (SNP) | VAF 7/33 reads (21%) | catalogued as rs1307804923; called by muse, mutect2, varscan2
- DNAH5 | c.6680G>T p.S2227I | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1444931826; called by muse, mutect2, varscan2
- DNAH9 | c.7295G>T p.W2432L | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs771825894, COSV52343530; called by muse, mutect2, varscan2
- DPF2 | c.899G>T p.R300L | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.279); catalogued as COSV52890101, COSV52890894; called by muse, mutect2, varscan2
- DYRK2 | c.37G>C p.A13P | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV59846618; called by muse, mutect2, varscan2
- EMILIN3 | c.2162G>C p.R721T | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs1024685904, COSV60034905; called by muse, mutect2, varscan2
- ERICH3 | c.3292C>A p.L1098I | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.037); catalogued as COSV100443065, COSV100444100; called by muse, mutect2, varscan2
- FAM102B | c.46G>C p.E16Q | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.573); catalogued as rs1176685942, COSV100899384; called by muse, mutect2, varscan2
- FAM135A | c.2843G>T p.C948F (on ENST00000370479 / NM_001351599.1; = p.C735F on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as COSV52054553; called by muse, mutect2, varscan2
- FAT3 | c.4022C>A p.S1341Y | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV53119608; called by muse, mutect2, varscan2
- FOXL1 | c.887C>T p.S296L | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.273); catalogued as rs1206206480; called by mutect2, varscan2
- FRS3 | c.640G>T p.E214* | Nonsense Mutation (SNP) | VAF 3/11 reads (27%) | catalogued as COSV52484839; called by muse, varscan2
- GALNT8 | c.752G>C p.R251P | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52894895; called by muse, mutect2, varscan2
- HES2 | c.13C>T p.R5C | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs1311586610; called by muse, mutect2, varscan2
- ICAM3 | c.783G>C p.Q261H | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.085); catalogued as rs1397125488; called by muse, mutect2, varscan2
- IL1A | c.652G>C p.E218Q | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.465); catalogued as COSV54519529; called by muse, varscan2
- KCNJ6 | c.1132G>C p.E378Q | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.57); PolyPhen benign (0.013); catalogued as COSV55713458; called by muse, varscan2
- KCNK18 | c.332G>T p.C111F | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.205); catalogued as rs756592283; called by muse, mutect2, varscan2
- KDM6A | c.508C>T p.H170Y | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV100938516; called by muse, varscan2
- KNTC1 | c.3070G>A p.E1024K | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.137); catalogued as rs760669670, COSV61082231; called by mutect2, varscan2
- LAMA5 | c.6193G>C p.G2065R | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs766271631; called by muse, mutect2, varscan2
- LATS2 | c.2369G>A p.R790Q | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66879567; called by muse, mutect2
- LPCAT4 | c.1508C>T p.S503L | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV59218938; called by muse, mutect2, varscan2
- LSM11 | c.986G>A p.R329Q | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs749494636; called by muse, varscan2
- MACF1 | c.17653G>A p.E5885K (on ENST00000372915; = p.E3927K on NM_012090.5) | Missense Mutation (SNP) | VAF 5/22 reads (23%) | catalogued as rs1166099239; called by muse, mutect2, varscan2
- MED13 | c.4589A>G p.N1530S | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs1194578657; called by muse, mutect2, varscan2
- METTL17 | c.112G>C p.D38H | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV59554855; called by muse, mutect2, varscan2
- METTL2A | c.336G>C p.L112F | Missense Mutation (SNP) | VAF 16/201 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.097); catalogued as COSV61045658; called by muse, mutect2
- MMUT | c.2168G>T p.G723V | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as CM1510871; called by muse, mutect2, varscan2
- MORC1 | c.324G>A p.M108I | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV51717703, COSV51730777; called by muse, varscan2
- MTREX | c.2113G>C p.E705Q | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.392); catalogued as COSV57925875; called by muse, mutect2
- MUC16 | c.19547C>A p.S6516Y | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.12); catalogued as COSV67451915; called by muse, varscan2
- MYCBPAP | c.2663C>G p.S888C | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.224); catalogued as rs1051238100; called by muse, mutect2, varscan2
- NACA2 | c.436C>G p.Q146E | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.054); catalogued as COSV101478573; called by muse, mutect2, varscan2
- NAV1 | c.376G>A p.G126R | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.919); catalogued as rs750081985; called by muse, varscan2
- NFASC | c.3025G>A p.D1009N | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs763737431; called by muse, mutect2, varscan2
- NMRAL1 | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated (0.58); PolyPhen benign (0.084); catalogued as rs759872001, COSV52059371; called by muse, mutect2, varscan2
- NUP98 | c.4633G>A p.E1545K (on ENST00000359171 / NM_001365126.1; = p.E1528K on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.266); catalogued as COSV100262089; called by muse, mutect2, varscan2
- NWD2 | c.59G>T p.R20L | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.046); catalogued as rs1258506325; called by muse, mutect2, varscan2
- OR10T2 | c.782G>T p.R261L | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as rs761365250, COSV57780410; called by muse, mutect2, varscan2
- OR13F1 | c.172C>A p.P58T | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs761571704; called by mutect2, varscan2
- OR2L2 | c.352G>T p.A118S | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.117); catalogued as COSV63562702; called by muse, mutect2, varscan2
- OR52E2 | c.53G>T p.G18V | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV58612233; called by muse, mutect2, varscan2
- OR5K3 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as COSV67350846; called by muse, mutect2
- ORC2 | c.332C>T p.S111L | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as rs1025269288, COSV52238547; called by muse, mutect2, varscan2
- OSBPL8 | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.024); catalogued as rs745744982; called by muse, mutect2, varscan2
- PAK1 | c.25C>G p.Q9E | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99583301; called by muse, mutect2
- PAX2 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1162043378, COSV62290451; called by muse, mutect2, varscan2
- PCDH11X | c.1185G>T p.R395S | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.566); catalogued as COSV100009118; called by muse, mutect2, varscan2
- PCDHB11 | c.1442G>T p.G481V | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV61312616; called by muse, mutect2, varscan2
- PDE1A | c.131G>C p.R44T | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV59531459; called by muse, mutect2, varscan2
- PDE3B | c.2428G>A p.E810K | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99963254; called by muse, varscan2
- PDLIM5 | c.286C>T p.Q96* | Nonsense Mutation (SNP) | VAF 18/150 reads (12%) | catalogued as COSV58753491; called by muse, mutect2, varscan2
- PHF3 | c.68G>C p.G23A | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100013274; called by muse, mutect2, varscan2
- PI4KB | c.1960G>C p.V654L (on ENST00000368873 / NM_001369623.1; = p.V666L on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.241); catalogued as COSV99650030; called by muse, varscan2
- PIEZO2 | c.2649C>A p.S883R | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.072); catalogued as rs1013706970, COSV57426751, COSV57431233, COSV57435670; called by muse, mutect2, varscan2
- PIK3C2G | c.2468C>A p.S823Y (on ENST00000676171; = p.S782Y on NM_004570.5) | Missense Mutation (SNP) | VAF 34/143 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV56835203; called by muse, mutect2, varscan2
- PKP1 | c.1216G>A p.A406T | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.524); catalogued as COSV99824710; called by muse, mutect2, varscan2
- PNN | c.403G>A p.D135N | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53768288; called by muse, mutect2, varscan2
- POLE | c.4883G>C p.G1628A | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as rs1233643471, COSV57674250; called by muse, mutect2, varscan2
- PTPN13 | c.7012C>T p.R2338* (on ENST00000411767 / NM_080683.3; = p.R2319* on NM_006264.3) | Nonsense Mutation (SNP) | VAF 8/22 reads (36%) | catalogued as rs975250120, COSV57405228; called by muse, mutect2, varscan2
- QSER1 | c.4210G>C p.E1404Q (on ENST00000399302; = p.E1533Q on NM_001076786.3) | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.083); catalogued as rs369707944, COSV67900751; called by mutect2, varscan2
- RAD54L2 | c.526C>T p.R176W | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.251); catalogued as rs201148857, COSV56577905, COSV56579496; called by muse, mutect2, varscan2
- RADX | c.460C>T p.H154Y | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.145); catalogued as rs1163731893, COSV100998889; called by muse, mutect2
- RAG2 | c.284G>T p.G95V | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100271462, COSV57559417; called by muse, mutect2, varscan2
- RBMXL2 | c.268G>C p.E90Q | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.143); catalogued as rs1397269593, COSV60979380; called by muse, mutect2, varscan2
- RFPL3 | c.223G>A p.D75N (on ENST00000249007 / NM_001098535.1; = p.D46N on NM_006604.2) | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.613); catalogued as rs759338505, COSV99966953; called by mutect2, varscan2
- RIC3 | c.343C>G p.L115V | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58305621; called by muse, mutect2, varscan2
- RIMS2 | c.4736C>G p.S1579* (on ENST00000666250 / NM_001348490.2; = p.S1150* on NM_014677.5 and 7 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 10/74 reads (14%) | catalogued as COSV51657623; called by mutect2, varscan2
- RTL1 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.071); catalogued as rs557343711, COSV66016864; called by mutect2, varscan2
- RYR2 | c.8731G>A p.E2911K | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as rs1553277510, COSV63703765; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SBDS | c.495G>A p.M165I | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.97); PolyPhen benign (0.003); catalogued as COSV55887367, COSV55888477; called by muse, mutect2, varscan2
- SEZ6L | c.1614C>G p.N538K | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.079); catalogued as COSV50670687; called by muse, mutect2, varscan2
- SGSM3 | c.1102A>G p.T368A | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs774684613; called by mutect2, varscan2
- SI | c.5197G>C p.D1733H | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); catalogued as COSV52298487; called by muse, varscan2
- SLC5A8 | c.822C>G p.F274L | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT tolerated (0.65); PolyPhen benign (0.005); catalogued as COSV73310464, COSV73310537; called by muse, mutect2, varscan2
- SMIM7 | c.75G>C p.K25N | Missense Mutation (SNP) | VAF 10/151 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.083); catalogued as COSV51817929; called by muse, mutect2
- SNX14 | c.1033G>C p.D345H (on ENST00000314673 / NM_001350535.1; = p.D301H on NM_020468.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100121545; called by muse, mutect2, varscan2
- SOS1 | c.1663G>C p.D555H | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67673817; called by muse, mutect2
- SOX5 | c.2099G>A p.S700N | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.842); catalogued as COSV58616335; called by muse, mutect2, varscan2
- SP9 | c.392C>T p.S131L | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.443); catalogued as rs1483269775; called by mutect2, varscan2
- SPAG4 | c.1093G>A p.D365N | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.077); catalogued as rs1435946829; called by muse, mutect2, varscan2
- SPAG5 | c.1687G>A p.E563K | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV100410597; called by mutect2, varscan2
- SRD5A1 | c.527G>A p.R176K | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs1382174314; called by muse, mutect2, varscan2
- SRGAP3 | c.2872G>T p.E958* | Nonsense Mutation (SNP) | VAF 5/29 reads (17%) | catalogued as COSV64533492; called by mutect2, varscan2
- STAT5A | c.1681-2A>T p.X561_splice | Splice Site (SNP) | VAF 9/68 reads (13%) | catalogued as COSV61807961; called by muse, mutect2
- SYT2 | c.304A>G p.M102V | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs767225887; called by muse, mutect2, varscan2
- TAF1C | c.625G>T p.E209* | Nonsense Mutation (SNP) | VAF 8/71 reads (11%) | catalogued as COSV58987183; called by muse, mutect2, varscan2
- TBC1D10A | c.202G>T p.E68* | Nonsense Mutation (SNP) | VAF 4/29 reads (14%) | catalogued as COSV53166041, COSV53166534; called by muse, varscan2
- TCN1 | c.681G>C p.K227N | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV57252116; called by muse, mutect2, varscan2
- TENM2 | c.4090G>T p.D1364Y (on ENST00000518659 / NM_001122679.2; = p.D1125Y on NM_001080428.3) | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV69129906; called by muse, mutect2, varscan2
- TGM6 | c.2024C>A p.S675Y | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV52480436; called by muse, mutect2, varscan2
- TMCC3 | c.1313C>A p.P438H | Missense Mutation (SNP) | VAF 60/168 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1425778146; called by muse, mutect2, varscan2
- TMEM26 | c.293G>A p.G98E | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1383460692; called by muse, mutect2, varscan2
- TNRC6A | c.5314G>T p.G1772C | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV100170242; called by muse, mutect2, varscan2
- TRAV16 | c.219G>C p.E73D | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs751860901; called by muse, mutect2, varscan2
- TRIM68 | c.472G>C p.E158Q | Missense Mutation (SNP) | VAF 18/211 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as COSV100331829, COSV56170555; called by muse, mutect2
- TTC12 | c.2035G>A p.E679K | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1565633247; called by muse, mutect2
- TTN | c.17510T>A p.I5837N (on ENST00000591111; = p.I4910N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/61 reads (7%) | PolyPhen benign (0.406); catalogued as COSV100609437; called by muse, mutect2
- UGT2B10 | c.1426C>T p.R476* | Nonsense Mutation (SNP) | VAF 16/127 reads (13%) | catalogued as rs754651977, COSV99608695; called by muse, mutect2, varscan2
- VCAN | c.7634T>C p.I2545T | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); catalogued as COSV99425465; called by muse, mutect2, varscan2
- WDFY4 | c.5161G>T p.V1721F | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.359); catalogued as rs960467505, COSV100304146; called by muse, mutect2, varscan2
- WDR36 | c.1261G>T p.G421* | Nonsense Mutation (SNP) | VAF 24/124 reads (19%) | catalogued as COSV72411438; called by muse, mutect2, varscan2
- WDR5B | c.557G>A p.S186N | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV58072354; called by muse, mutect2
- WNK3 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV63613585; called by muse, mutect2, varscan2
- XIRP2 | c.7876C>G p.P2626A (on ENST00000628543; = p.P2801A on NM_152381.6) | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV99745801; called by muse, mutect2, varscan2
- ZACN | c.532C>G p.L178V | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0.096); catalogued as COSV58035576; called by muse, mutect2, varscan2
- ZKSCAN7 | c.1495G>A p.E499K | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV56271629; called by muse, mutect2
- ZNF780A | c.1147C>T p.H383Y | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61816441; called by muse, mutect2, varscan2
- ABCC12 | c.2560G>A p.V854M | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ABLIM1 | c.1309G>A p.E437K | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.038); called by mutect2, varscan2
- ABTB2 | c.1623G>C p.L541F | Missense Mutation (SNP) | VAF 14/141 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AC245033.1 | c.1580G>A p.R527K | Missense Mutation (SNP) | VAF 22/222 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ADGRB1 | c.212C>A p.T71K | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- ADGRB2 | c.1149del p.S384Pfs*40 | Frame Shift Del (DEL) | VAF 3/25 reads (12%) | called by pindel, varscan2
- AHNAK | c.15790G>T p.G5264* | Nonsense Mutation (SNP) | VAF 29/103 reads (28%) | called by muse, mutect2, varscan2
- AKAP3 | c.1517C>T p.P506L | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.005); called by muse, varscan2
- ALG12 | c.1238+5G>C | Splice Region (SNP) | VAF 14/85 reads (16%) | called by muse, mutect2, varscan2
- ALX1 | c.531G>C p.Q177H | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- ANKRD35 | c.1952G>A p.R651Q | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.04); called by muse, mutect2
- APBA2 | c.490C>A p.Q164K | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- APEH | c.1025C>T p.S342L | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- APOBEC2 | c.408C>G p.I136M | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ASCC3 | c.4493A>G p.D1498G | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ASXL3 | c.1784A>T p.Q595L | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- ATP1A2 | c.761G>A p.G254D | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); called by muse, varscan2
- ATP2B2 | c.3097-1G>A p.X1033_splice (on ENST00000352432; = p.X999_splice on NM_001683.5) | Splice Site (SNP) | VAF 20/123 reads (16%) | called by muse, varscan2
- AXDND1 | c.2653A>T p.I885F | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- BAP1 | c.1832A>T p.E611V | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- BCL10 | c.514C>G p.L172V | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.12); called by mutect2, varscan2
- BCL11A | c.1963G>C p.E655Q (on ENST00000335712 / NM_001365609.1; = p.E689Q on NM_018014.4) | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- BCL9L | c.1611G>C p.Q537H | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2
- C11orf87 | c.402G>T p.Q134H | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- C7orf57 | c.510G>A p.L170= | Splice Region (SNP) | VAF 18/63 reads (29%) | called by muse, mutect2, varscan2
- CAPN14 | c.1845G>C p.M615I | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CCDC122 | c.421G>T p.E141* | Nonsense Mutation (SNP) | VAF 8/48 reads (17%) | called by muse, mutect2, varscan2
- CCDC47 | c.273T>A p.D91E | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- CD3G | c.52C>T p.Q18* | Nonsense Mutation (SNP) | VAF 8/116 reads (7%) | called by muse, mutect2
- CDC42BPG | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, varscan2
- CDC45 | c.175G>C p.E59Q | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- CDCA5 | c.563+7G>T | Splice Region (SNP) | VAF 9/64 reads (14%) | called by muse, mutect2, varscan2
- CDH26 | c.580G>T p.E194* | Nonsense Mutation (SNP) | VAF 8/44 reads (18%) | called by muse, varscan2
- CDH9 | c.60C>A p.D20E | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDKL5 | c.2287G>A p.E763K | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.76); called by muse, mutect2
- CFAP206 | c.1228G>C p.D410H | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- CLTA | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- CMTM2 | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- CNTNAP1 | c.132_133del p.Y44* | Frame Shift Del (DEL) | VAF 4/35 reads (11%) | called by mutect2, pindel
- COL4A1 | c.959G>A p.G320E | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- COL6A3 | c.9420C>A p.F3140L | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CRYBA2 | c.311A>G p.N104S | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.86); PolyPhen benign (0); called by mutect2, varscan2
- CTR9 | c.2070C>G p.I690M | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- CX3CR1 | c.46G>A p.D16N | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2
- DAO | c.175C>T p.P59S | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2
- DIXDC1 | c.1432G>A p.D478N (on ENST00000440460 / NM_001037954.4; = p.D267N on NM_033425.4) | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.51); called by muse, mutect2, varscan2
- DNAJC24 | c.62C>G p.S21C | Missense Mutation (SNP) | VAF 21/143 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- DOCK10 | c.2077-1G>A p.X693_splice | Splice Site (SNP) | VAF 14/56 reads (25%) | called by muse, mutect2, varscan2
- DYM | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.79); PolyPhen benign (0.001); called by muse, mutect2
- DYNC2I1 | c.2077C>G p.L693V | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EDNRB | c.1296C>A p.S432R (on ENST00000377211 / NM_001201397.1; = p.S342R on NM_000115.5) | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- EPHA5 | c.411C>A p.C137* | Nonsense Mutation (SNP) | VAF 6/34 reads (18%) | called by muse, mutect2, varscan2
- EXOC3 | c.803G>C p.R268T | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- EXT2 | c.715G>C p.E239Q (on ENST00000343631; = p.E272Q on NM_000401.3) | Missense Mutation (SNP) | VAF 26/208 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- FAM13B | c.367C>T p.Q123* | Nonsense Mutation (SNP) | VAF 6/20 reads (30%) | called by muse, mutect2
- FANCD2 | c.4279G>A p.E1427K | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.015); called by mutect2, varscan2
- FIBCD1 | c.931G>T p.G311W | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- FSHB | c.347G>T p.G116V | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GAA | c.2341G>C p.E781Q | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- GBF1 | c.250C>G p.L84V | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- GDF9 | c.964G>C p.E322Q | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- GDPGP1 | c.93T>A p.Y31* | Nonsense Mutation (SNP) | VAF 17/70 reads (24%) | called by muse, mutect2, varscan2
- GLP2R | c.326C>G p.S109C | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- GPSM2 | c.1636G>A p.E546K | Missense Mutation (SNP) | VAF 29/173 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.185); called by muse, varscan2
- GPSM2 | c.1774G>C p.E592Q | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.368); called by muse, varscan2
- GREB1 | c.2597C>G p.S866* | Nonsense Mutation (SNP) | VAF 13/134 reads (10%) | called by muse, mutect2
- GRIA2 | c.617G>T p.R206L | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GXYLT2 | c.667G>C p.D223H | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- HAUS8 | c.628G>C p.D210H | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.54); called by mutect2, varscan2
- HEATR6 | c.1398G>C p.L466F | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- HEATR9 | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- HMCN1 | c.15569G>C p.C5190S | Missense Mutation (SNP) | VAF 12/206 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- HSD3B2 | c.242C>G p.T81S | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- IFNGR2 | c.352G>C p.E118Q | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- IFT88 | c.2219G>A p.R740K (on ENST00000319980 / NM_001318493.2; = p.R731K on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- IGFBP6 | c.46C>G p.L16V | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.987); called by muse, mutect2
- IGHV3-38 | c.196T>C p.W66R | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- IGKV6D-41 | c.147dup p.G50Wfs*48 | Frame Shift Ins (INS) | VAF 19/101 reads (19%) | called by mutect2, pindel, varscan2
- IL16 | c.3083C>A p.S1028Y (on ENST00000302987 / NM_172217.5; = p.S327Y on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.96); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- IL21 | c.441G>A p.M147I | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- INPP1 | c.594G>T p.M198I | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- IPO7 | c.2812G>A p.E938K | Missense Mutation (SNP) | VAF 22/187 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IZUMO1 | c.520C>G p.Q174E | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KANSL1 | c.2305G>A p.E769K | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- KCNJ9 | c.299G>A p.C100Y | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIAA2012 | c.2743T>A p.S915T | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (1); called by muse, mutect2, varscan2
- KLHDC2 | c.91G>T p.E31* | Nonsense Mutation (SNP) | VAF 8/43 reads (19%) | called by muse, mutect2, varscan2
- LCT | c.1557C>A p.F519L | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- LEMD3 | c.1208_1232del p.P403Lfs*27 | Frame Shift Del (DEL) | VAF 12/72 reads (17%) | called by mutect2, pindel
- LGR5 | c.793C>G p.H265D | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- LIFR | c.434C>G p.S145C | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- LRBA | c.4406A>T p.D1469V | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.203); called by muse, mutect2
- LRP1B | c.10579T>C p.C3527R | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRP2 | c.7663G>T p.G2555W | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRRC72 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.41); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LRRIQ1 | c.2531A>G p.Y844C | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by mutect2, varscan2
- LY86 | c.285G>C p.L95F | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- MACF1 | c.4786G>C p.E1596Q | Missense Mutation (SNP) | VAF 6/50 reads (12%) | called by muse, mutect2, varscan2
- MAF | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MAGI3 | c.1501G>A p.E501K | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.207); called by muse, mutect2
- MANBA | c.1918C>G p.Q640E (on ENST00000642252; = p.Q594E on NM_005908.4) | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- MDGA2 | c.387G>C p.L129F | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- METTL25 | c.1714G>A p.E572K | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- MICU2 | c.1162C>T p.L388F | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, varscan2
- MLLT3 | c.1310G>C p.R437T | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- MMRN1 | c.1396G>A p.V466I | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- MON1A | c.379G>T p.E127* | Nonsense Mutation (SNP) | VAF 9/52 reads (17%) | called by muse, mutect2, varscan2
- MRC1 | c.1809G>T p.M603I | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- MSH5 | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.282); called by muse, mutect2
- MTERF2 | c.758G>C p.G253A | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.737); called by mutect2, varscan2
- MTPAP | c.8_11delinsAA p.V3Efs*38 | Frame Shift Del (DEL) | VAF 7/72 reads (10%) | called by pindel, varscan2*
- NEK4 | c.2328del p.R777Dfs*2 | Frame Shift Del (DEL) | VAF 6/48 reads (13%) | called by mutect2, pindel, varscan2
- NELL2 | c.1142A>T p.E381V | Missense Mutation (SNP) | VAF 37/152 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- NHP2 | c.230+5G>A | Splice Region (SNP) | VAF 24/172 reads (14%) | called by muse, mutect2, varscan2
- NPAP1 | c.2330C>G p.P777R | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.635); called by muse, varscan2
- NRBP1 | c.591del p.I198Sfs*6 | Frame Shift Del (DEL) | VAF 22/70 reads (31%) | called by mutect2, pindel, varscan2
- NRBP1 | c.1303G>A p.E435K | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); called by muse, mutect2
- NRIP3 | c.71G>C p.R24P | Missense Mutation (SNP) | VAF 9/122 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.578); called by muse, mutect2
- NRXN1 | c.3863T>A p.I1288N | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- NRXN3 | c.2662C>T p.Q888* (on ENST00000335750 / NM_001330195.2; = p.Q515* on NM_004796.6) | Nonsense Mutation (SNP) | VAF 20/102 reads (20%) | called by muse, mutect2, varscan2
- NTRK3 | c.491G>T p.C164F | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NUCB1 | c.1333G>A p.E445K | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); called by muse, mutect2
- NUCB2 | c.124A>C p.S42R | Missense Mutation (SNP) | VAF 18/147 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- OGT | c.1688C>T p.S563F | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); called by muse, mutect2
- OLFM4 | c.94C>A p.P32T | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR2M3 | c.704G>C p.R235P | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.657); called by muse, mutect2, varscan2
- OR2T12 | c.452C>A p.A151E | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.958); called by mutect2, varscan2
- OR51M1 | c.383T>A p.L128H | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- OR5D16 | c.164C>G p.P55R | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- OR9K2 | c.263T>A p.L88Q (on ENST00000305377; = p.L66Q on NM_001005243.1) | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PAPPA2 | c.4840C>A p.L1614M | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- PARP2 | c.10C>G p.R4G | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- PARVB | c.623dup p.V209Gfs*44 | Frame Shift Ins (INS) | VAF 5/33 reads (15%) | called by mutect2, pindel, varscan2
- PCDH10 | c.2926C>T p.P976S | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PCDHGA3 | c.2302C>A p.L768M | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- PLCL2 | c.2621dup p.L874Ffs*9 (on ENST00000615277 / NM_001144382.2; = p.L748Ffs*9 on NM_015184.5) | Frame Shift Ins (INS) | VAF 4/20 reads (20%) | called by mutect2, pindel
- PLOD2 | c.502G>T p.G168* | Nonsense Mutation (SNP) | VAF 11/83 reads (13%) | called by muse, mutect2, varscan2
- PNLIP | c.598C>T p.Q200* | Nonsense Mutation (SNP) | VAF 11/78 reads (14%) | called by muse, mutect2
- POLR1H | c.366G>C p.E122D | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- PPM1E | c.1366G>C p.E456Q | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- PPRC1 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PRDM5 | c.1795C>T p.R599C | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PRICKLE1 | c.1628C>T p.S543F | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PROS1 | c.1256G>T p.G419V | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- PSMB10 | c.778C>G p.L260V | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PSMC1 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PTH2R | c.1160C>A p.T387N | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- PTPN21 | c.466G>A p.D156N | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- PTPN4 | c.2086G>A p.V696I | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.979); called by muse, varscan2
- PTPRD | c.4084G>C p.E1362Q | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.409); called by muse, mutect2, varscan2
- PTPRQ | c.2689G>T p.D897Y (on ENST00000616559; = p.D855Y on NM_001145026.2) | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); called by muse, varscan2
- R3HDM2 | c.2378A>T p.Q793L | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.031); called by muse, varscan2
- RAB3GAP2 | c.1471G>A p.V491M | Missense Mutation (SNP) | VAF 11/121 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- RAG2 | c.1165G>C p.E389Q | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RBM46 | c.425G>A p.R142K | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.605); called by muse, varscan2
- RCVRN | c.495T>A p.D165E | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RFX1 | c.1632G>C p.Q544H | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- RHCG | c.1163G>A p.R388K | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.84); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- RHOA | c.230C>T p.T77I | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- RIN1 | c.2185G>A p.E729K | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- RIOK1 | c.1237G>T p.E413* | Nonsense Mutation (SNP) | VAF 21/114 reads (18%) | called by muse, mutect2, varscan2
- RIT2 | c.477T>A p.F159L | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ROBO1 | c.2593G>T p.E865* | Nonsense Mutation (SNP) | VAF 6/16 reads (38%) | called by muse, mutect2, varscan2
- RPS6KA6 | c.289G>A p.D97N | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.074); called by muse, mutect2
- RTL1 | c.535G>A p.D179N | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SBK3 | c.545G>A p.G182E | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- SCD5 | c.43G>A p.D15N | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- SEC24A | c.1940G>C p.G647A | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SEC24C | c.925C>T p.Q309* | Nonsense Mutation (SNP) | VAF 8/82 reads (10%) | called by muse, mutect2
- SEMA3C | c.556G>T p.G186* | Nonsense Mutation (SNP) | VAF 6/24 reads (25%) | called by muse, mutect2, varscan2
- SERPINI2 | c.262G>T p.V88L | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, varscan2
- SETDB2 | c.1983G>C p.Q661H | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- SH3KBP1 | c.1238G>C p.R413T | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SHB | c.917A>G p.Q306R | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.32); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SLC36A2 | c.343A>C p.R115= | Splice Region (SNP) | VAF 25/116 reads (22%) | called by muse, mutect2, varscan2
- SLC66A2 | c.98A>G p.Y33C | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SORL1 | c.1551G>T p.K517N | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.995); called by muse, varscan2
- SOX6 | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- SPATA31A1 | c.361G>C p.D121H | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SPTA1 | c.4421G>T p.R1474L | Missense Mutation (SNP) | VAF 35/162 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- SPTBN5 | c.6980G>T p.R2327L | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SRPK1 | c.1882G>A p.D628N | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- STAC2 | c.659C>G p.S220C | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); called by muse, mutect2
- SVEP1 | c.9532C>T p.P3178S | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SWAP70 | c.409G>C p.E137Q | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- TAB2 | c.1675G>C p.D559H | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- TACR2 | c.496C>T p.Q166* | Nonsense Mutation (SNP) | VAF 9/67 reads (13%) | called by muse, mutect2
- TAF2 | c.1532C>G p.S511C | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- TBC1D2B | c.1914A>T p.E638D | Missense Mutation (SNP) | VAF 11/169 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.018); called by muse, mutect2
- TBXAS1 | c.1021G>T p.A341S | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TCF20 | c.2678G>C p.R893T | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- TENT2 | c.120C>G p.F40L | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- TF | c.865G>T p.A289S | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.784); called by mutect2, varscan2
- TF | c.1403C>A p.S468Y | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TGIF2LX | c.34C>A p.Q12K | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TLL2 | c.2763G>C p.W921C | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TM9SF2 | c.1750G>C p.E584Q | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- TMEM207 | c.119T>C p.V40A | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.173); called by muse, varscan2
- TNXB | c.2731G>C p.E911Q | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- TRIM32 | c.581G>T p.R194M | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- TRIOBP | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TRPC4AP | c.2246G>T p.C749F | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- TTBK1 | c.265C>A p.H89N | Missense Mutation (SNP) | VAF 28/174 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TTL | c.883C>A p.L295I | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- TTN | c.45142G>T p.E15048* (on ENST00000591111; = p.E7624* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 18/70 reads (26%) | called by muse, mutect2, varscan2
- TTN | c.17509A>C p.I5837L (on ENST00000591111; = p.I4910L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/64 reads (6%) | PolyPhen benign (0.006); called by muse, mutect2
- UBAP1 | c.740C>A p.S247* | Nonsense Mutation (SNP) | VAF 9/80 reads (11%) | called by mutect2, varscan2
- UBE2NL | c.306C>G p.I102M | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.892); called by muse, mutect2
- UBE2NL | c.307C>A p.R103S | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.287); called by muse, varscan2
- UBR1 | c.988G>A p.D330N | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- UBR4 | c.596C>T p.S199L | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- UNC80 | c.1022C>A p.P341H | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- UNC80 | c.4915G>T p.V1639L | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- USH2A | c.15281del p.P5094Rfs*8 | Frame Shift Del (DEL) | VAF 11/88 reads (13%) | called by mutect2, pindel, varscan2
- USP13 | c.2519A>C p.H840P | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- USP48 | c.125G>T p.G42V | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.203); called by muse, varscan2
- WDR47 | c.2165G>C p.S722T (on ENST00000369962 / NM_001142551.2; = p.S723T on NM_014969.5) | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.272); called by muse, mutect2
- XK | c.1308G>C p.L436F | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- XKRX | c.869G>T p.R290I | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.193); called by muse, mutect2
- XRN2 | c.2199-1G>C p.X733_splice | Splice Site (SNP) | VAF 5/38 reads (13%) | called by muse, mutect2, varscan2
- ZBED5 | c.1558G>C p.E520Q | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- ZBTB7B | c.1532del p.P511Rfs*37 (on ENST00000292176; = p.P545Rfs*37 on NM_001252406.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 6/22 reads (27%) | called by mutect2, pindel, varscan2
- ZFHX4 | c.10165G>T p.D3389Y | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); called by mutect2, varscan2
- ZFP36L1 | c.1009G>A p.D337N | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- ZMYM3 | c.1900G>A p.E634K | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- ZNF304 | c.872dup p.L291Ffs*21 | Frame Shift Ins (INS) | VAF 6/19 reads (32%) | called by mutect2, pindel, varscan2
- ZNF410 | c.370C>G p.L124V | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); called by muse, mutect2
- ZNF521 | c.162G>C p.Q54H | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.44); called by muse, mutect2, varscan2
- ZNF577 | c.523C>G p.Q175E | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- ZNF623 | c.762G>C p.Q254H | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); called by muse, mutect2
- ZNF638 | c.1031C>G p.S344C | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2
- ZNF662 | c.857G>T p.S286I | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.761); called by muse, varscan2
- ZNF716 | c.1197G>C p.K399N | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, varscan2
- ZNF729 | c.158-1G>T p.X53_splice | Splice Site (SNP) | VAF 4/14 reads (29%) | called by muse, varscan2
- ZNF831 | c.2824C>A p.L942I | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- ZNF90 | c.809C>G p.S270C | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, varscan2
- ACTN2 | c.1914G>C p.L638= | Silent (SNP) | VAF 8/81 reads (10%) | catalogued as COSV63977144; called by muse, mutect2, varscan2
- AHNAK2 | c.8775G>C p.L2925= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as COSV60924061; called by mutect2, varscan2
- AHNAK2 | c.4263G>T p.V1421= | Silent (SNP) | VAF 14/64 reads (22%) | called by muse, mutect2, varscan2
- AK5 | c.1581C>A p.P527= (on ENST00000354567 / NM_174858.3; = p.P501= on NM_012093.4) | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV100642658; called by mutect2, varscan2
- ASAH2 | c.1089C>T p.I363= | Silent (SNP) | VAF 26/168 reads (15%) | called by muse, mutect2, varscan2
- BNIP1 | c.51C>T p.V17= | Silent (SNP) | VAF 18/73 reads (25%) | catalogued as rs774205290; called by muse, mutect2, varscan2
- BST2 | c.102C>T p.I34= | Silent (SNP) | VAF 13/114 reads (11%) | catalogued as rs1408717756, COSV53089403; called by muse, mutect2, varscan2
- C2orf16 | c.2865G>T p.V955= | Silent (SNP) | VAF 12/69 reads (17%) | called by mutect2, varscan2
- C2orf69 | c.216C>G p.L72= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as rs187090652; called by muse, mutect2
- C5orf24 | c.162G>A p.Q54= | Silent (SNP) | VAF 16/91 reads (18%) | catalogued as COSV57542818; called by muse, mutect2, varscan2
- CACNA1D | c.3732C>T p.F1244= (on ENST00000350061 / NM_001128840.3; = p.F1264= on NM_000720.4) | Silent (SNP) | VAF 17/107 reads (16%) | called by muse, mutect2, varscan2
- CACNB2 | c.87G>T p.V29= | Silent (SNP) | VAF 14/67 reads (21%) | catalogued as rs758806288; ClinVar: likely benign; called by muse, mutect2, varscan2
- CALML5 | c.207C>T p.F69= | Silent (SNP) | VAF 10/88 reads (11%) | catalogued as COSV66702754; called by muse, mutect2
- CAMKK1 | c.1155G>A p.L385= | Silent (SNP) | VAF 9/89 reads (10%) | called by muse, mutect2, varscan2
- CCDC88B | c.3792G>A p.L1264= | Silent (SNP) | VAF 4/40 reads (10%) | called by muse, varscan2
- CDH15 | c.1584C>G p.L528= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as rs1394662566, COSV57023676; called by muse, mutect2, varscan2
- CDH18 | c.768C>A p.I256= | Silent (SNP) | VAF 9/69 reads (13%) | called by muse, mutect2, varscan2
- CDH23 | c.4854G>C p.T1618= | Silent (SNP) | VAF 7/15 reads (47%) | called by muse, mutect2, varscan2
- CELSR3 | c.3201C>T p.F1067= | Silent (SNP) | VAF 24/141 reads (17%) | catalogued as COSV51116549; called by muse, mutect2, varscan2
- COL15A1 | c.3738G>T p.L1246= | Silent (SNP) | VAF 12/95 reads (13%) | called by muse, mutect2, varscan2
- CTSC | c.1104G>T p.G368= | Silent (SNP) | VAF 19/38 reads (50%) | catalogued as rs1479718336; called by muse, mutect2, varscan2
- DCAF4L2 | c.258C>G p.L86= | Silent (SNP) | VAF 18/84 reads (21%) | called by muse, mutect2, varscan2
- DCDC1 | c.5136C>T p.P1712= (on ENST00000597505 / NM_001367979.1; = p.P819= on NM_020869.3) | Silent (SNP) | VAF 24/157 reads (15%) | catalogued as rs763760199; called by muse, varscan2
- DIDO1 | c.5916C>T p.V1972= | Silent (SNP) | VAF 16/108 reads (15%) | called by muse, mutect2, varscan2
- DNAAF1 | c.1737G>A p.L579= | Silent (SNP) | VAF 9/66 reads (14%) | called by mutect2, varscan2
- DNAH10 | c.2373C>G p.L791= (on ENST00000409039; = p.L730= on NM_207437.3) | Silent (SNP) | VAF 17/121 reads (14%) | called by muse, mutect2, varscan2
- DOCK5 | c.1146C>G p.V382= | Silent (SNP) | VAF 6/48 reads (13%) | called by muse, mutect2, varscan2
- EPHA7 | c.1371G>A p.R457= | Silent (SNP) | VAF 12/79 reads (15%) | called by muse, mutect2, varscan2
- EPHB1 | c.1179C>T p.I393= | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as COSV101212563; called by muse, mutect2, varscan2
- FAM102A | c.1083G>A p.T361= (on ENST00000373095 / NM_001035254.3; = p.T219= on NM_203305.2) | Silent (SNP) | VAF 11/70 reads (16%) | catalogued as rs1240966595; called by muse, mutect2, varscan2
- FAM186A | c.6582G>C p.L2194= | Silent (SNP) | VAF 10/57 reads (18%) | called by muse, mutect2, varscan2
- FBH1 | c.1638G>C p.G546= (on ENST00000362091 / NM_178150.3; = p.G597= on NM_032807.4) | Silent (SNP) | VAF 22/137 reads (16%) | called by muse, mutect2, varscan2
- FBLN7 | c.912C>T p.G304= | Silent (SNP) | VAF 8/52 reads (15%) | called by muse, varscan2
- FEM1C | c.345C>G p.T115= | Silent (SNP) | VAF 16/125 reads (13%) | called by muse, mutect2, varscan2
- FGF9 | c.348C>T p.L116= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as rs761526644; called by muse, mutect2, varscan2
- GOLGB1 | c.7491C>T p.L2497= | Silent (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2, varscan2
- GPLD1 | c.1731C>T p.F577= | Silent (SNP) | VAF 8/84 reads (10%) | catalogued as rs551677592; called by mutect2, varscan2
- GPR158 | c.405C>T p.F135= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as rs749740727; called by muse, mutect2, varscan2
- GRIN2D | c.2289C>G p.L763= | Silent (SNP) | VAF 3/32 reads (9%) | called by muse, mutect2
- HBA2 | c.363G>A p.A121= | Silent (SNP) | VAF 14/117 reads (12%) | catalogued as rs1213128257; called by muse, mutect2, varscan2
- HECW1 | c.3354G>A p.K1118= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV101222483; called by muse, varscan2
- HOXC8 | c.279G>T p.A93= | Silent (SNP) | VAF 15/123 reads (12%) | called by muse, mutect2, varscan2
- IGHV3-11 | c.126A>G p.A42= | Silent (SNP) | VAF 8/93 reads (9%) | catalogued as rs575672055; called by muse, mutect2
- ITPR3 | c.6663C>T p.F2221= | Silent (SNP) | VAF 9/85 reads (11%) | catalogued as rs1414086971, COSV65415348; called by muse, mutect2, varscan2
- KNDC1 | c.4908C>T p.F1636= | Silent (SNP) | VAF 6/50 reads (12%) | called by muse, varscan2
- LARS1 | c.1218G>A p.L406= (on ENST00000394434 / NM_020117.11; = p.L379= on NM_016460.3) | Silent (SNP) | VAF 19/111 reads (17%) | called by muse, mutect2, varscan2
- LDLRAD4 | c.565C>T p.L189= | Silent (SNP) | VAF 9/59 reads (15%) | called by muse, mutect2, varscan2
- LRPPRC | c.1074A>G p.L358= | Silent (SNP) | VAF 23/163 reads (14%) | called by muse, mutect2, varscan2
- LRRC52 | c.228C>G p.L76= | Silent (SNP) | VAF 18/77 reads (23%) | called by muse, mutect2, varscan2
- LRRC8A | c.1899C>T p.I633= | Silent (SNP) | VAF 18/105 reads (17%) | catalogued as COSV52185801; called by muse, mutect2, varscan2
- MAPK14 | c.93C>A p.G31= | Silent (SNP) | VAF 9/79 reads (11%) | called by mutect2, varscan2
- MINAR1 | c.612C>A p.T204= | Silent (SNP) | VAF 29/101 reads (29%) | called by muse, mutect2, varscan2
- MPHOSPH9 | c.3243G>A p.K1081= | Silent (SNP) | VAF 26/176 reads (15%) | catalogued as rs933678013; called by muse, mutect2, varscan2
- MROH2B | c.4083C>T p.V1361= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as rs779752867, COSV68182909; called by mutect2, varscan2
- MUC4 | c.13695G>T p.L4565= (on ENST00000463781 / NM_018406.7; = p.L329= on NM_004532.6) | Silent (SNP) | VAF 11/72 reads (15%) | called by muse, mutect2, varscan2
- MYH15 | c.3594G>A p.E1198= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as COSV99843067; called by muse, mutect2, varscan2
- MYOG | c.168G>A p.G56= | Silent (SNP) | VAF 3/17 reads (18%) | catalogued as COSV54095277, COSV54096354; called by muse, mutect2
- OR10Q1 | c.183C>T p.T61= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as COSV100372423; called by muse, mutect2, varscan2
- OR1L3 | c.717C>T p.S239= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as rs1564233367, COSV100506292; called by muse, mutect2, varscan2
- OR4C12 | c.273C>A p.S91= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV58859577; called by muse, varscan2
- OR4K13 | c.729C>T p.H243= | Silent (SNP) | VAF 8/62 reads (13%) | called by muse, mutect2
- OR5A2 | c.162T>C p.S54= | Silent (SNP) | VAF 25/82 reads (30%) | called by muse, mutect2, varscan2
- PAPPA | c.1731C>T p.I577= | Silent (SNP) | VAF 18/83 reads (22%) | called by mutect2, varscan2
- PCDHA1 | c.1815G>T p.A605= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as COSV65373021, COSV65377355; called by muse, mutect2, varscan2
- PCID2 | c.756G>T p.L252= | Silent (SNP) | VAF 9/72 reads (13%) | called by muse, mutect2, varscan2
- PDZRN4 | c.1770G>A p.Q590= (on ENST00000402685 / NM_001164595.2; = p.Q332= on NM_013377.4) | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as COSV100115863; called by muse, mutect2, varscan2
- PELI1 | c.1083C>T p.T361= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as COSV100735190; called by muse, varscan2
- PEX5L | c.678C>A p.A226= | Silent (SNP) | VAF 30/136 reads (22%) | called by muse, mutect2, varscan2
- PIF1 | c.1101G>A p.K367= | Silent (SNP) | VAF 6/30 reads (20%) | called by muse, mutect2, varscan2
- PIGQ | c.135C>T p.V45= | Silent (SNP) | VAF 11/36 reads (31%) | called by muse, mutect2, varscan2
- PLA2G4A | c.1476C>T p.F492= | Silent (SNP) | VAF 9/99 reads (9%) | catalogued as COSV66553238; called by muse, mutect2
- PLPPR4 | c.273A>T p.T91= | Silent (SNP) | VAF 6/38 reads (16%) | called by mutect2, varscan2
- PLXNA4 | c.5097C>A p.I1699= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as rs1338257541; called by muse, mutect2, varscan2
- POU3F1 | c.270A>G p.L90= | Silent (SNP) | VAF 4/28 reads (14%) | called by muse, varscan2
- PRDM6 | c.381C>A p.V127= | Silent (SNP) | VAF 6/32 reads (19%) | called by mutect2, varscan2
- PSTPIP2 | c.171C>T p.L57= | Silent (SNP) | VAF 13/102 reads (13%) | called by mutect2, varscan2
- PTH2R | c.207A>T p.G69= | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as COSV55914600; called by muse, mutect2, varscan2
- RASAL1 | c.1719G>A p.L573= | Silent (SNP) | VAF 9/68 reads (13%) | called by muse, mutect2, varscan2
- RBP1 | c.294G>A p.Q98= (on ENST00000619087 / NM_001365940.2; = p.Q160= on NM_002899.5) | Silent (SNP) | VAF 8/74 reads (11%) | called by muse, varscan2
- RGS3 | c.3495G>A p.K1165= (on ENST00000350696 / NM_001282923.2; = p.K884= on NM_130795.4) | Silent (SNP) | VAF 15/112 reads (13%) | catalogued as rs1245789289; called by muse, mutect2, varscan2
- RHOG | c.201C>T p.L67= | Silent (SNP) | VAF 10/88 reads (11%) | catalogued as rs1423638236; called by muse, varscan2
- RNF145 | c.1185T>C p.Y395= (on ENST00000424310 / NM_001199383.2; = p.Y423= on NM_144726.2) | Silent (SNP) | VAF 19/69 reads (28%) | catalogued as COSV99193843; called by muse, mutect2, varscan2
- RYR1 | c.2982G>T p.V994= | Silent (SNP) | VAF 10/88 reads (11%) | catalogued as rs1277103290; called by muse, varscan2
- SCARF1 | c.597C>T p.S199= | Silent (SNP) | VAF 8/26 reads (31%) | called by muse, mutect2, varscan2
- SCGB2A1 | c.39C>A p.L13= | Silent (SNP) | VAF 5/42 reads (12%) | called by muse, mutect2, varscan2
- SCN4A | c.4071C>T p.I1357= | Silent (SNP) | VAF 4/8 reads (50%) | called by muse, mutect2
- SLC16A12 | c.390C>T p.I130= | Silent (SNP) | VAF 23/114 reads (20%) | catalogued as rs774279072, COSV57949572; called by muse, mutect2, varscan2
- SLC18A3 | c.93G>A p.Q31= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV60319359; called by muse, varscan2
- SLC24A3 | c.1662G>A p.L554= | Silent (SNP) | VAF 19/144 reads (13%) | catalogued as rs1439550872; called by muse, mutect2, varscan2
- SLC35A5 | c.1069C>T p.L357= | Silent (SNP) | VAF 23/143 reads (16%) | called by muse, mutect2, varscan2
- SPAG1 | c.2397G>A p.P799= | Silent (SNP) | VAF 7/63 reads (11%) | catalogued as rs775891909; called by mutect2, varscan2
- SPTB | c.4221G>T p.P1407= | Silent (SNP) | VAF 10/71 reads (14%) | called by muse, mutect2, varscan2
- SPTBN1 | c.6912C>G p.S2304= | Silent (SNP) | VAF 10/52 reads (19%) | called by mutect2, varscan2
- ST3GAL5 | c.108G>A p.V36= | Silent (SNP) | VAF 13/63 reads (21%) | called by muse, mutect2, varscan2
- STXBP5 | c.2748G>T p.V916= (on ENST00000321680 / NM_001127715.2; = p.V880= on NM_139244.4) | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as COSV99470419; called by muse, mutect2, varscan2
- SYNRG | c.3417G>A p.L1139= | Silent (SNP) | VAF 8/78 reads (10%) | called by muse, mutect2
- TAF1L | c.5280G>T p.L1760= | Silent (SNP) | VAF 30/88 reads (34%) | called by muse, mutect2, varscan2
- TDRD9 | c.2712C>T p.V904= | Silent (SNP) | VAF 7/26 reads (27%) | called by muse, mutect2, varscan2
- TEX13B | c.630C>T p.P210= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV100258336; called by muse, mutect2, varscan2
- TFCP2L1 | c.1068C>T p.I356= | Silent (SNP) | VAF 29/87 reads (33%) | called by muse, mutect2, varscan2
- TMPO | c.75G>T p.V25= | Silent (SNP) | VAF 21/177 reads (12%) | called by muse, mutect2, varscan2
- TMPRSS3 | c.264G>A p.L88= | Silent (SNP) | VAF 7/81 reads (9%) | catalogued as rs1233200337, COSV52300103; called by muse, mutect2
- TRANK1 | c.5787C>T p.G1929= | Silent (SNP) | VAF 6/29 reads (21%) | called by mutect2, varscan2
- UGT2B4 | c.867G>A p.P289= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs772557481, COSV59316585, COSV59320138; called by mutect2, varscan2
- VWA5A | c.1398A>T p.V466= | Silent (SNP) | VAF 15/41 reads (37%) | called by muse, mutect2, varscan2
- YKT6 | c.193C>T p.L65= | Silent (SNP) | VAF 7/64 reads (11%) | called by muse, varscan2
- ZDHHC13 | c.1530C>G p.L510= | Silent (SNP) | VAF 8/125 reads (6%) | called by muse, mutect2
- ZFHX4 | c.2277C>A p.S759= | Silent (SNP) | VAF 14/65 reads (22%) | called by muse, mutect2, varscan2
- ZFP91 | c.540C>T p.L180= | Silent (SNP) | VAF 13/84 reads (15%) | called by muse, mutect2, varscan2
- ZNF184 | c.228G>A p.V76= | Silent (SNP) | VAF 19/116 reads (16%) | called by muse, mutect2, varscan2
- ZNF536 | c.2634G>C p.S878= | Silent (SNP) | VAF 3/13 reads (23%) | called by mutect2, varscan2
- ZNF600 | c.1902G>C p.G634= | Silent (SNP) | VAF 16/86 reads (19%) | called by muse, mutect2, varscan2
- ZNF749 | c.9G>A p.L3= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as rs540975939, COSV61945020; called by muse, mutect2, varscan2
- ABLIM1 | c.1041+2654C>G | Intron (SNP) | VAF 5/39 reads (13%) | called by muse, mutect2, varscan2
- AC011487.2 | n.1225G>C | RNA (SNP) | VAF 24/89 reads (27%) | called by muse, mutect2, varscan2
- AC092675.1 | n.459-147C>A | Intron (SNP) | VAF 26/111 reads (23%) | called by muse, mutect2, varscan2
- AC093512.2 | c.*888+40G>C | Intron (SNP) | VAF 44/99 reads (44%) | called by muse, mutect2, varscan2
- AC107023.1 | chr12:40445543 C>T | 5'Flank (SNP) | VAF 6/40 reads (15%) | catalogued as rs776662405; called by mutect2, varscan2
- AC136604.1 | n.384A>G | RNA (SNP) | VAF 15/108 reads (14%) | called by muse, mutect2, varscan2
- ACSF3 | c.1614-2966G>T | Intron (SNP) | VAF 52/151 reads (34%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73849418 G>C | 5'Flank (SNP) | VAF 8/96 reads (8%) | called by muse, mutect2
- ALG9 | c.1713-1922G>A | Intron (SNP) | VAF 23/95 reads (24%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65501478 T>C | 5'Flank (SNP) | VAF 8/38 reads (21%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65503270 C>G | 5'Flank (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2, varscan2
- APOB | c.2436+133G>T | Intron (SNP) | VAF 21/95 reads (22%) | called by muse, mutect2, varscan2
- ARHGAP9 | c.-203-20G>T | Intron (SNP) | VAF 5/22 reads (23%) | catalogued as rs745545883; called by mutect2, varscan2
- BCL2L11 | c.499-2681C>T | Intron (SNP) | VAF 19/109 reads (17%) | catalogued as rs1472856901; called by muse, mutect2, varscan2
- BORCS5 | chr12:12356787 C>G | 5'Flank (SNP) | VAF 30/276 reads (11%) | called by muse, mutect2
- C3orf18 | c.235-775C>G | Intron (SNP) | VAF 28/125 reads (22%) | called by muse, mutect2, varscan2
- CCER1 | chr12:90947914 C>T | 3'Flank (SNP) | VAF 10/41 reads (24%) | catalogued as rs1463754441; called by muse, mutect2
- CHD4 | c.4197+30G>A | Intron (SNP) | VAF 8/116 reads (7%) | called by muse, mutect2
- CLUHP11 | n.747G>T | RNA (SNP) | VAF 20/92 reads (22%) | called by muse, mutect2, varscan2
- CSMD3 | c.178+59939G>A | Intron (SNP) | VAF 27/171 reads (16%) | catalogued as COSV52266600; called by muse, mutect2, varscan2
- CSRP3 | c.-18G>C | 5'UTR (SNP) | VAF 20/170 reads (12%) | called by muse, mutect2, varscan2
- CTSLP8 | n.336C>G | RNA (SNP) | VAF 7/82 reads (9%) | called by muse, mutect2
- CUEDC2 | chr10:102436565 G>A | 5'Flank (SNP) | VAF 4/34 reads (12%) | called by muse, varscan2
- CUL4A | chr13:113208553 G>A | 5'Flank (SNP) | VAF 30/151 reads (20%) | called by muse, mutect2, varscan2
- DEAF1 | c.1593+2638A>G | Intron (SNP) | VAF 9/39 reads (23%) | called by mutect2, varscan2
- DEPDC7 | c.73+516G>C | Intron (SNP) | VAF 14/143 reads (10%) | called by muse, mutect2
- DPY19L2P1 | n.1748G>C | RNA (SNP) | VAF 7/72 reads (10%) | called by muse, mutect2, varscan2
- DPY19L2P2 | n.788G>A | RNA (SNP) | VAF 11/137 reads (8%) | called by muse, mutect2
- EPOR | c.*96G>A | 3'UTR (SNP) | VAF 11/63 reads (17%) | called by muse, varscan2
- FBXL8 | chr16:67164482 C>T | 3'Flank (SNP) | VAF 6/82 reads (7%) | called by muse, mutect2
- FBXL8 | chr16:67164483 C>T | 3'Flank (SNP) | VAF 6/83 reads (7%) | called by muse, mutect2
- FOLH1B | n.958T>A | RNA (SNP) | VAF 12/36 reads (33%) | called by muse, mutect2, varscan2
- FRMD8P1 | n.672G>T | RNA (SNP) | VAF 8/33 reads (24%) | called by muse, mutect2, varscan2
- GABRB3 | c.545-31G>T | Intron (SNP) | VAF 15/69 reads (22%) | called by muse, mutect2, varscan2
- GSC | c.-11G>C | 5'UTR (SNP) | VAF 3/11 reads (27%) | called by muse, varscan2
- KIAA1109 | c.10540-234C>T | Intron (SNP) | VAF 12/56 reads (21%) | called by muse, mutect2, varscan2
- KIAA1586 | c.-30A>G | 5'UTR (SNP) | VAF 14/73 reads (19%) | catalogued as rs1257725062; called by muse, mutect2, varscan2
- KY | c.1090+75G>A | Intron (SNP) | VAF 8/48 reads (17%) | called by muse, mutect2, varscan2
- LINC01622 | n.63G>T | RNA (SNP) | VAF 12/76 reads (16%) | catalogued as rs1359766703; called by muse, mutect2, varscan2
- LINC02843 | n.255A>T | RNA (SNP) | VAF 4/16 reads (25%) | called by muse, mutect2
- LMF1 | c.*586C>G | 3'UTR (SNP) | VAF 10/54 reads (19%) | called by muse, mutect2, varscan2
- MAK | c.*38G>C | 3'UTR (SNP) | VAF 6/35 reads (17%) | catalogued as COSV100504518; called by muse, mutect2, varscan2
- MAP2K3 | c.49+3084C>G | Intron (SNP) | VAF 11/77 reads (14%) | catalogued as COSV57568838; called by muse, mutect2, varscan2
- MCFD2 | chr2:46917277 G>T | 5'Flank (SNP) | VAF 6/29 reads (21%) | catalogued as COSV60177774; called by muse, varscan2
- MCM10 | c.*4G>A | 3'UTR (SNP) | VAF 7/36 reads (19%) | catalogued as rs549527948, COSV101098057; called by muse, mutect2, varscan2
- MIR514A1 | n.71G>T | RNA (SNP) | VAF 20/85 reads (24%) | called by muse, mutect2, varscan2
- MROH2B | c.-24T>C | 5'UTR (SNP) | VAF 9/57 reads (16%) | called by muse, varscan2
- MTUS1 | c.2624-12799C>G | Intron (SNP) | VAF 5/48 reads (10%) | catalogued as rs747813241; called by mutect2, varscan2
- MYADML | n.946C>A | RNA (SNP) | VAF 6/27 reads (22%) | called by muse, mutect2, varscan2
- NACA | c.70+4484C>A | Intron (SNP) | VAF 24/178 reads (13%) | called by muse, mutect2, varscan2
- NDOR1 | c.-10G>A | 5'UTR (SNP) | VAF 9/127 reads (7%) | catalogued as rs1045948233; called by muse, mutect2
- NECAB1 | c.259+20C>A | Intron (SNP) | VAF 5/24 reads (21%) | called by muse, mutect2, varscan2
- NELL1 | c.1549+54876G>T | Intron (SNP) | VAF 43/110 reads (39%) | called by muse, mutect2, varscan2
- NRXN1 | c.3365-110228C>A | Intron (SNP) | VAF 12/60 reads (20%) | called by muse, mutect2, varscan2
- PAX6 | c.142-47C>A | Intron (SNP) | VAF 8/48 reads (17%) | catalogued as COSV53792915; called by muse, mutect2, varscan2
- PDE10A | c.106+91807G>T | Intron (SNP) | VAF 17/51 reads (33%) | called by muse, varscan2
- PEX16 | c.*50C>G | 3'UTR (SNP) | VAF 7/49 reads (14%) | called by muse, mutect2, varscan2
- PIPSL | n.1695T>A | RNA (SNP) | VAF 15/161 reads (9%) | called by muse, mutect2
- PRKN | c.-2C>T | 5'UTR (SNP) | VAF 8/53 reads (15%) | catalogued as rs1281249287; called by muse, mutect2, varscan2
- RAB24 | c.118-10C>G | Intron (SNP) | VAF 6/43 reads (14%) | catalogued as rs776937539; called by muse, mutect2, varscan2
- RAD21 | chr8:116875524 A>T | 5'Flank (SNP) | VAF 5/25 reads (20%) | called by muse, mutect2, varscan2
- REG1B | c.-12C>G | 5'UTR (SNP) | VAF 8/43 reads (19%) | called by muse, mutect2, varscan2
- RGS11 | c.657+397G>C | Intron (SNP) | VAF 7/75 reads (9%) | called by muse, mutect2, varscan2
- SEPTIN4 | c.*17G>C | 3'UTR (SNP) | VAF 8/36 reads (22%) | called by muse, mutect2
- SIGLEC10 | c.755-54C>T | Intron (SNP) | VAF 3/8 reads (38%) | called by muse, mutect2
- SLAMF1 | c.*439C>G | 3'UTR (SNP) | VAF 18/114 reads (16%) | catalogued as COSV52501057; called by muse, mutect2, varscan2
- SLC25A26 | c.-87C>A | 5'UTR (SNP) | VAF 12/66 reads (18%) | called by muse, varscan2
- SLC26A7 | c.1935+235A>T | Intron (SNP) | VAF 10/70 reads (14%) | called by muse, mutect2, varscan2
- SLC66A1L | n.272C>G | RNA (SNP) | VAF 20/104 reads (19%) | called by muse, mutect2, varscan2
- SMIM7 | c.121+188G>A | Intron (SNP) | VAF 12/54 reads (22%) | called by muse, mutect2
- SNORD114-18 | n.41G>A | RNA (SNP) | VAF 9/79 reads (11%) | catalogued as rs553443798; called by muse, mutect2, varscan2
- SNORD52 | chr6:31835444 G>C | 5'Flank (SNP) | VAF 16/292 reads (5%) | called by muse, mutect2
- SPINDOC | c.935-3781G>C | Intron (SNP) | VAF 13/122 reads (11%) | called by muse, mutect2, varscan2
- SRSF5 | c.297-32C>T | Intron (SNP) | VAF 14/104 reads (13%) | catalogued as rs759725960; called by muse, mutect2, varscan2
- SSH1 | c.111-13624A>G | Intron (SNP) | VAF 8/93 reads (9%) | catalogued as rs1382553106, COSV58468320; called by muse, mutect2
- SSPOP | n.3690G>C | RNA (SNP) | VAF 4/22 reads (18%) | called by muse, varscan2
- STX3 | c.*6G>C | 3'UTR (SNP) | VAF 21/57 reads (37%) | called by muse, mutect2, varscan2
- TGFBR3 | c.*356A>T | 3'UTR (SNP) | VAF 15/82 reads (18%) | called by muse, mutect2, varscan2
- TMEM135 | c.*3800C>T | 3'UTR (SNP) | VAF 8/66 reads (12%) | called by muse, mutect2
- TMEM38B | c.660+899G>C | Intron (SNP) | VAF 9/61 reads (15%) | called by muse, mutect2, varscan2
- TNFSF4 | c.153+1704A>G | Intron (SNP) | VAF 10/35 reads (29%) | called by muse, mutect2, varscan2
- TRPM6 | c.841+12A>T | Intron (SNP) | VAF 19/116 reads (16%) | called by muse, varscan2
- UBA6 | c.960+50G>A | Intron (SNP) | VAF 7/69 reads (10%) | called by muse, mutect2, varscan2
- USP27X | chrX:49878614 G>C | 5'Flank (SNP) | VAF 5/59 reads (8%) | called by muse, mutect2
- VWCE | c.206-50C>A | Intron (SNP) | VAF 6/42 reads (14%) | called by muse, mutect2, varscan2
- WASF4P | n.658G>T | RNA (SNP) | VAF 9/96 reads (9%) | called by muse, mutect2
- ZEB2 | c.73+4255G>T | Intron (SNP) | VAF 14/115 reads (12%) | called by muse, varscan2
- ZNF483 | c.412+13G>A | Intron (SNP) | VAF 9/88 reads (10%) | called by muse, mutect2
- ZNF84 | c.*4278C>T | 3'UTR (SNP) | VAF 23/201 reads (11%) | called by muse, mutect2, varscan2
